Somatic mutation profile of tumor specimen ALCH-B26S-TTP1-A (aliquot ALCH-B26S-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B26S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.9 years (23,695 days).
Specimen ALCH-B26S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 357d02cf-f8c8-4e65-8959-febc62801003.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B26S-NB1-A (Blood Derived Normal), aliquot ALCH-B26S-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b338f6c-d697-4abc-a4c8-967d077691bd

The open-access MAF lists 55 somatic variants for this specimen: 37 protein-altering or splice-affecting, 9 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 9, Intron 6, Nonsense Mutation 4, RNA 3, Splice Site 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 86/567 reads (15%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.428T>A p.V143E | Missense Mutation (SNP) | VAF 29/213 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1511132, COSV52737174, COSV52760297, COSV52868891; called by muse, mutect2, varscan2
- BTN3A1 | c.566C>T p.T189I | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV50024475; called by muse, mutect2
- CSF2RA | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs749182596, COSV62624548; called by muse, mutect2
- GUCY1A2 | c.25G>T p.E9* | Nonsense Mutation (SNP) | VAF 30/163 reads (18%) | catalogued as COSV99030269; called by muse, mutect2, varscan2
- LAMB4 | c.891T>A p.C297* | Nonsense Mutation (SNP) | VAF 54/180 reads (30%) | catalogued as rs1433967803; called by muse, mutect2, varscan2
- NEB | c.4970C>T p.T1657I | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs145632757; called by muse, mutect2
- OR13A1 | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV100980973; called by muse, mutect2
- PLCL2 | c.3076G>A p.V1026I (on ENST00000615277 / NM_001144382.2; = p.V900I on NM_015184.5) | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs776218297, COSV67622459, COSV67624118; called by muse, mutect2
- TEX13A | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.097); catalogued as rs782459107; called by muse, mutect2, varscan2
- TEX13A | c.171C>A p.S57R | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.221); catalogued as rs782590107, COSV100782108; called by muse, mutect2, varscan2
- TNRC18 | c.2188C>T p.R730W | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs767038330; called by muse, mutect2, varscan2
- ZNF2 | c.973C>G p.P325A (on ENST00000611147 / NM_001291605.2; = p.P312A on NM_021088.4) | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs779824720, COSV54636105, COSV54638353; called by muse, mutect2, varscan2
- ADGRV1 | c.10063A>G p.I3355V | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.01); called by muse, mutect2
- ATL2 | c.347G>T p.R116I | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CACNA1F | c.5156+1G>C p.X1719_splice | Splice Site (SNP) | VAF 30/530 reads (6%) | called by muse, mutect2
- CCNB3 | c.3230C>T p.T1077I | Missense Mutation (SNP) | VAF 27/536 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2
- CDKL4 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- FBXO6 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 22/219 reads (10%) | called by muse, mutect2
- HCN4 | c.251C>A p.A84E | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HIVEP1 | c.3198T>A p.C1066* | Nonsense Mutation (SNP) | VAF 6/101 reads (6%) | called by muse, mutect2
- IFI16 | c.1496C>G p.T499R | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGSF9 | c.3398C>T p.A1133V (on ENST00000368094 / NM_001135050.2; = p.A1117V on NM_020789.4) | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); called by muse, mutect2
- KCNT1 | c.1466G>A p.C489Y (on ENST00000488444; = p.C508Y on NM_020822.3) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- KDM6A | c.2431A>T p.T811S | Missense Mutation (SNP) | VAF 32/504 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2
- KIF18A | c.1997G>T p.R666I | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- NCAN | c.3520C>A p.P1174T | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PNPLA7 | c.1553G>T p.C518F | Missense Mutation (SNP) | VAF 21/304 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.05); called by muse, mutect2
- RTN4 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); called by muse, mutect2
- SUCO | c.898A>T p.T300S | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.118); called by muse, mutect2
- TLR8 | c.3089A>G p.Y1030C (on ENST00000218032 / NM_138636.5; = p.Y1048C on NM_016610.4) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TMC6 | c.2197C>T p.L733= | Splice Region (SNP) | VAF 37/189 reads (20%) | called by muse, mutect2, varscan2
- TMEM176B | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 68/279 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, varscan2
- TREX1 | c.41T>G p.L14R (on ENST00000625293 / NM_033629.6; = p.L4R on NM_007248.5) | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- UCK2 | c.356+2T>C p.X119_splice | Splice Site (SNP) | VAF 12/173 reads (7%) | called by muse, mutect2
- VASN | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.072); called by muse, mutect2
- ZFHX4 | c.6122C>A p.T2041N | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DCBLD1 | c.930A>G p.P310= | Silent (SNP) | VAF 33/251 reads (13%) | called by muse, mutect2, varscan2
- DSC3 | c.834G>A p.T278= | Silent (SNP) | VAF 62/346 reads (18%) | catalogued as rs926254758, COSV64573128; called by muse, mutect2, varscan2
- EIF3I | c.75C>T p.L25= | Silent (SNP) | VAF 18/217 reads (8%) | catalogued as rs775639469; called by muse, mutect2
- GRIK5 | c.216G>A p.R72= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- LAMA5 | c.3456G>C p.R1152= | Silent (SNP) | VAF 11/183 reads (6%) | called by muse, mutect2
- MAGEA4 | c.678G>C p.L226= | Silent (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- NOL6 | c.2763C>T p.L921= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2
- TP53 | c.429G>T p.V143= | Silent (SNP) | VAF 31/212 reads (15%) | catalogued as COSV52730128, COSV52994834, COSV53016789; called by muse, mutect2, varscan2
- TYRO3 | c.1665C>T p.D555= | Silent (SNP) | VAF 6/124 reads (5%) | catalogued as rs1353587293; called by muse, mutect2
- ADGB | c.4818+5502G>A | Intron (SNP) | VAF 37/261 reads (14%) | catalogued as rs528746419; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+906G>A | Intron (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- ILF3 | c.2059+477T>A | Intron (SNP) | VAF 20/298 reads (7%) | called by muse, mutect2
- OR2L1P | n.468C>A | RNA (SNP) | VAF 45/349 reads (13%) | called by muse, mutect2, varscan2
- PLCD1 | c.1137+17C>A | Intron (SNP) | VAF 20/394 reads (5%) | called by muse, mutect2
- PYHIN1 | c.579+246G>T | Intron (SNP) | VAF 13/378 reads (3%) | called by muse, mutect2
- RSPH9 | c.671-4335C>T | Intron (SNP) | VAF 20/147 reads (14%) | catalogued as rs750166414, COSV64537666; called by muse, varscan2
- TTC3P1 | n.5047G>T | RNA (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- XIST | n.9995C>T | RNA (SNP) | VAF 16/378 reads (4%) | called by muse, mutect2
